Somatic mutation profile of tumor specimen ALCH-ADO6-TTP1-A (aliquot ALCH-ADO6-TTP1-A-1-0-D-A565-36) from ALCHEMIST case ALCH-ADO6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 52.0 years (19,007 days).
Specimen ALCH-ADO6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 677085e1-db69-46d8-9f4b-cbe332395416.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADO6-NB1-A (Blood Derived Normal), aliquot ALCH-ADO6-NB1-A-1-0-D-A565-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e099e80c-1fc7-4d91-ada2-c32c13443163

The open-access MAF lists 149 somatic variants for this specimen: 92 protein-altering or splice-affecting, 29 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 29, Intron 10, RNA 5, 3'UTR 4, 5'Flank 4, 5'UTR 3, 3'Flank 2, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYO7A | c.3719G>A p.R1240Q | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs111033178, CM990900; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 50/932 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ALK | c.2430C>G p.S810R | Missense Mutation (SNP) | VAF 33/586 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as rs150292405, COSV66583379; called by muse, mutect2
- APC | c.6068G>C p.R2023T | Missense Mutation (SNP) | VAF 63/616 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57380275, COSV57391455; called by muse, mutect2
- ARRDC5 | c.599C>A p.T200K (on ENST00000381781; = p.T186K on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/510 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.165); catalogued as COSV101108236; called by muse, mutect2
- ATP6V0A4 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 44/765 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.397); catalogued as rs1277901726; called by muse, mutect2
- DDHD2 | c.1819C>G p.P607A | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV68157901; called by muse, mutect2
- DOCK4 | c.2834G>C p.R945T | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV101447952; called by muse, mutect2
- FAR2 | c.467C>G p.S156* | Nonsense Mutation (SNP) | VAF 12/342 reads (4%) | catalogued as COSV51726305; called by muse, mutect2
- FCGR2A | c.170C>A p.S57Y (on ENST00000271450 / NM_001136219.3; = p.S56Y on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/365 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.249); catalogued as COSV54836916; called by muse, mutect2
- GPD1 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV56548384; called by muse, mutect2
- H2BW1 | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV99475091; called by muse, mutect2, varscan2
- HMGN5 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.24); catalogued as rs757874765, COSV63918149; called by muse, mutect2
- INSYN2B | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.109); catalogued as COSV56953969; called by muse, mutect2
- KCNT1 | c.618G>T p.T206= (on ENST00000488444; = p.T225= on NM_020822.3) | Splice Region (SNP) | VAF 44/303 reads (15%) | catalogued as rs773255063, COSV53704965, COSV53712077; called by muse, mutect2, varscan2
- KCNV1 | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as COSV52089543; called by muse, mutect2
- KIR3DL2 | c.154C>G p.R52G | Missense Mutation (SNP) | VAF 50/932 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.694); catalogued as COSV54390813; called by muse, mutect2
- KIRREL1 | c.1171G>C p.G391R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63291959; called by mutect2, varscan2
- LTF | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51610481; called by muse, mutect2
- MARK1 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100857167; called by muse, mutect2
- PAPPA2 | c.1704C>A p.S568R | Missense Mutation (SNP) | VAF 34/347 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV100867013; called by muse, mutect2
- PLCH1 | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58186138; called by muse, mutect2
- RUNX1T1 | c.1234C>A p.H412N (on ENST00000265814 / NM_001198628.1; = p.H385N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/586 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV99749577; called by muse, mutect2
- SDR16C5 | c.785A>G p.K262R | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs1563438702; called by muse, mutect2
- SGCD | c.660C>G p.C220W (on ENST00000435422 / NM_001128209.2; = p.C221W on NM_000337.5) | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61918343; called by muse, mutect2
- STARD9 | c.10093G>A p.G3365S | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.447); catalogued as rs1181990774; called by muse, mutect2
- ZNF585A | c.1397A>G p.Y466C (on ENST00000292841 / NM_001288800.2; = p.Y411C on NM_152655.3) | Missense Mutation (SNP) | VAF 26/424 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs761343878; called by muse, mutect2
- ABCA13 | c.5071G>T p.D1691Y | Missense Mutation (SNP) | VAF 37/588 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.774); called by muse, mutect2
- ABCD1 | c.1247C>G p.T416R | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ABHD17C | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 42/648 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- AGO3 | c.2453T>A p.L818H | Missense Mutation (SNP) | VAF 19/311 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ARID3B | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- ATP12A | c.2126C>A p.S709Y | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BEST3 | c.919A>T p.T307S | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2
- BRD4 | c.621G>T p.Q207H | Missense Mutation (SNP) | VAF 28/704 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- CACNA1A | c.2059G>T p.G687C | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CCHCR1 | c.1067G>T p.S356I | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2
- CDRT4 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 30/510 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.406); called by muse, mutect2
- CNR1 | c.406C>A p.L136M | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.232); called by muse, mutect2
- COL4A4 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 28/760 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CRYBG3 | c.2864A>C p.Q955P | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CYP11B2 | c.614T>C p.F205S | Missense Mutation (SNP) | VAF 68/534 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- DGKK | c.3706A>G p.K1236E | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DMBT1 | c.7228G>C p.D2410H (on ENST00000338354 / NM_001377530.1; = p.D1653H on NM_004406.3) | Missense Mutation (SNP) | VAF 40/629 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); called by muse, mutect2
- DNAH1 | c.5851G>T p.V1951L | Missense Mutation (SNP) | VAF 40/488 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- DSG4 | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- EBPL | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 22/462 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, mutect2
- EPHB1 | c.102G>T p.W34C | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM47C | c.1489C>A p.H497N | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.942); called by muse, mutect2
- FCN2 | c.554C>A p.A185D | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2
- FLT4 | c.4005C>A p.S1335R | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.422); called by muse, mutect2
- FZD6 | c.482G>A p.C161Y | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GPR22 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 23/522 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- HNRNPUL2 | c.810C>G p.F270L | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.112); called by muse, mutect2
- HOXB6 | c.365A>T p.K122M | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- HTR7 | c.1177A>T p.T393S | Missense Mutation (SNP) | VAF 20/420 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.038); called by muse, mutect2
- JUP | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KIR2DL3 | c.860C>A p.T287K | Missense Mutation (SNP) | VAF 20/544 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2
- MAMDC2 | c.793A>T p.T265S | Missense Mutation (SNP) | VAF 50/528 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.137); called by muse, mutect2
- MCFD2 | c.253A>T p.N85Y | Missense Mutation (SNP) | VAF 36/594 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MFSD9 | c.832A>C p.K278Q | Missense Mutation (SNP) | VAF 28/606 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2
- MROH6 | c.1406T>C p.L469P | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- NES | c.4727G>T p.G1576V | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- NEUROD6 | c.818T>A p.L273Q | Missense Mutation (SNP) | VAF 14/341 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- NOXO1 | c.53T>C p.I18T | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2
- OR10H5 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.968); called by muse, mutect2
- OR4C5 | c.659T>C p.V220A | Missense Mutation (SNP) | VAF 30/496 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.49); called by muse, mutect2
- OTOG | c.5986C>A p.P1996T | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.617); called by muse, mutect2
- P3H3 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 40/428 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.441); called by muse, mutect2
- PCDHB11 | c.1894G>C p.E632Q | Missense Mutation (SNP) | VAF 26/611 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PCF11 | c.2752G>A p.E918K | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- PRICKLE1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 30/618 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PUS7L | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RELN | c.7003T>C p.W2335R | Missense Mutation (SNP) | VAF 28/557 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2
- RUNDC3B | c.143T>G p.I48S | Missense Mutation (SNP) | VAF 35/613 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2
- SLC16A1 | c.994T>C p.F332L | Missense Mutation (SNP) | VAF 38/694 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.181); called by muse, mutect2
- SLC35G4 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 24/668 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- SLC44A5 | c.1106G>T p.S369I | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- SLC7A9 | c.1453G>T p.D485Y | Missense Mutation (SNP) | VAF 28/788 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- SLCO1C1 | c.863C>A p.A288E | Missense Mutation (SNP) | VAF 28/582 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- SLITRK5 | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.688); called by muse, mutect2
- SPEF2 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 44/670 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.81); called by muse, mutect2
- SPTA1 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 28/710 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- STRC | c.3557A>T p.Q1186L | Missense Mutation (SNP) | VAF 36/722 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.075); called by muse, mutect2
- SYNPO2 | c.2314C>G p.P772A | Missense Mutation (SNP) | VAF 32/462 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.083); called by muse, mutect2
- TMC8 | c.1081C>A p.L361M | Missense Mutation (SNP) | VAF 56/822 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2
- TTN | c.756A>T p.K252N | Missense Mutation (SNP) | VAF 40/772 reads (5%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- USP9X | c.1984A>T p.R662* | Nonsense Mutation (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- VWA5B1 | c.3468C>A p.H1156Q (on ENST00000375079; = p.H1151Q on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/506 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- XDH | c.56A>T p.N19I | Missense Mutation (SNP) | VAF 41/750 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- ZFHX4 | c.418T>A p.Y140N | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- ZNF469 | c.6945G>T p.Q2315H (on ENST00000437464; = p.Q2343H on NM_001367624.2) | Missense Mutation (SNP) | VAF 15/198 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2
- ACCSL | c.1245C>A p.A415= | Silent (SNP) | VAF 22/364 reads (6%) | called by muse, mutect2
- ATRNL1 | c.906T>A p.S302= | Silent (SNP) | VAF 42/576 reads (7%) | called by muse, mutect2
- BOC | c.2217T>C p.S739= | Silent (SNP) | VAF 45/306 reads (15%) | called by muse, mutect2, varscan2
- CARD10 | c.1326C>T p.G442= | Silent (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- CCR6 | c.405C>G p.L135= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as rs934610897; called by muse, mutect2
- CFAP44 | c.30T>C p.D10= | Silent (SNP) | VAF 37/356 reads (10%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.3192C>T p.L1064= | Silent (SNP) | VAF 22/352 reads (6%) | catalogued as COSV62162601; called by muse, mutect2
- COL22A1 | c.3591A>T p.P1197= | Silent (SNP) | VAF 20/377 reads (5%) | called by muse, mutect2
- DOCK1 | c.2253C>G p.R751= | Silent (SNP) | VAF 14/450 reads (3%) | called by muse, mutect2
- EPHA5 | c.1776C>A p.V592= | Silent (SNP) | VAF 17/337 reads (5%) | called by muse, mutect2
- FANCM | c.1236C>G p.L412= | Silent (SNP) | VAF 22/402 reads (5%) | catalogued as rs1476021559; called by muse, mutect2
- HIP1 | c.2874A>G p.S958= | Silent (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- IL36RN | c.135C>T p.V45= | Silent (SNP) | VAF 32/532 reads (6%) | called by muse, mutect2
- LSM8 | c.141C>T p.S47= | Silent (SNP) | VAF 20/370 reads (5%) | called by muse, mutect2
- MAN2B1 | c.1920C>T p.T640= | Silent (SNP) | VAF 30/750 reads (4%) | called by muse, mutect2
- MROH6 | c.1407G>T p.L469= | Silent (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- MUC4 | c.10854T>A p.P3618= | Silent (SNP) | VAF 87/801 reads (11%) | called by muse, varscan2
- OBSCN | c.22131G>T p.L7377= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- PCSK2 | c.966C>T p.Y322= | Silent (SNP) | VAF 31/554 reads (6%) | catalogued as rs1279204596, COSV52726986, COSV52732993; called by muse, mutect2
- PLP1 | c.747T>A p.A249= | Silent (SNP) | VAF 48/470 reads (10%) | called by muse, mutect2
- PSAP | c.753T>C p.I251= | Silent (SNP) | VAF 34/661 reads (5%) | called by muse, mutect2
- ROR2 | c.2074C>A p.R692= | Silent (SNP) | VAF 32/320 reads (10%) | called by muse, mutect2
- SCG3 | c.45C>A p.L15= | Silent (SNP) | VAF 44/748 reads (6%) | called by muse, mutect2
- SGCD | c.561C>T p.F187= (on ENST00000435422 / NM_001128209.2; = p.F188= on NM_000337.5) | Silent (SNP) | VAF 28/282 reads (10%) | called by muse, mutect2
- STAMBP | c.1026G>A p.A342= | Silent (SNP) | VAF 18/450 reads (4%) | catalogued as rs1319666970, COSV59897706; called by muse, mutect2
- TAF1L | c.3837A>G p.L1279= | Silent (SNP) | VAF 54/435 reads (12%) | called by muse, mutect2, varscan2
- TIMM50 | c.921G>T p.P307= | Silent (SNP) | VAF 10/226 reads (4%) | catalogued as COSV100067908; called by muse, mutect2
- TMEM268 | c.720G>T p.V240= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as COSV99938812; called by mutect2, varscan2
- ZEB1 | c.1191A>T p.P397= | Silent (SNP) | VAF 8/147 reads (5%) | called by muse, mutect2
- AASS | c.-41C>T | 5'UTR (SNP) | VAF 17/395 reads (4%) | called by muse, mutect2
- AASS | c.-42G>A | 5'UTR (SNP) | VAF 16/386 reads (4%) | called by muse, mutect2
- ACP5 | c.736-41C>G | Intron (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- AGTR1 | c.*14T>C | 3'UTR (SNP) | VAF 21/586 reads (4%) | called by muse, mutect2
- AL162726.3 | n.255+83800A>G | Intron (SNP) | VAF 65/527 reads (12%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505395 A>T | 5'Flank (SNP) | VAF 8/140 reads (6%) | called by muse, mutect2
- C19orf12 | chr19:29699908 T>A | 3'Flank (SNP) | VAF 18/509 reads (4%) | called by muse, mutect2
- CFL1 | chr11:65861331 A>C | 5'Flank (SNP) | VAF 21/532 reads (4%) | called by muse, mutect2
- DENND10P1 | n.685C>A | RNA (SNP) | VAF 54/527 reads (10%) | called by muse, mutect2, varscan2
- FLJ40288 | n.818C>G | RNA (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- KIF1A | c.2555+826G>T | Intron (SNP) | VAF 33/316 reads (10%) | called by muse, mutect2
- LINC02210-CRHR1 | c.-493+11516G>T | Intron (SNP) | VAF 22/226 reads (10%) | called by muse, mutect2
- LPAL2 | n.387A>G | RNA (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- MUCL3 | c.947-726C>G | Intron (SNP) | VAF 22/370 reads (6%) | called by muse, mutect2
- PCDHB6 | chr5:141156104 C>A | 3'Flank (SNP) | VAF 28/375 reads (7%) | called by muse, mutect2
- PRPF4B | c.-2A>G | 5'UTR (SNP) | VAF 36/472 reads (8%) | catalogued as rs1376209417; called by muse, mutect2
- PTPRC | c.100+1702G>A | Intron (SNP) | VAF 37/342 reads (11%) | catalogued as COSV61421443; called by muse, mutect2
- SART3 | c.1117-40A>G | Intron (SNP) | VAF 10/250 reads (4%) | catalogued as rs1040210141; called by muse, mutect2
- SCN4B | c.*2482T>C | 3'UTR (SNP) | VAF 36/615 reads (6%) | called by muse, mutect2
- SEC61A1 | chr3:128051890 C>A | 5'Flank (SNP) | VAF 42/326 reads (13%) | called by muse, mutect2, varscan2
- SLC12A2 | c.3436-42A>G | Intron (SNP) | VAF 16/193 reads (8%) | called by muse, mutect2
- SNORD115-23 | n.9G>T | RNA (SNP) | VAF 18/299 reads (6%) | catalogued as rs1385339556; called by muse, mutect2
- SNX14 | c.140+4657C>T | Intron (SNP) | VAF 24/328 reads (7%) | called by muse, mutect2
- SPRR2G | c.*37A>T | 3'UTR (SNP) | VAF 18/403 reads (4%) | catalogued as COSV100907397; called by muse, mutect2
- SUMF2 | c.396+144A>G | Intron (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- TUBB4AP1 | n.518C>A | RNA (SNP) | VAF 18/227 reads (8%) | called by muse, mutect2
- WDR86 | chr7:151411721 G>A | 5'Flank (SNP) | VAF 13/264 reads (5%) | called by muse, mutect2
- ZNF777 | c.*216C>T | 3'UTR (SNP) | VAF 12/160 reads (8%) | catalogued as rs1279209707; called by muse, mutect2
